Somatic mutation profile of tumor specimen 0DDROS from CCDI case PBBPFG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.6 years (1,305 days).
Specimen 0DDROS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52695788-55c2-4eab-a1cc-d5e44d346092.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDROT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06bc932c-ee3a-4634-b69c-fc6d094192b4

The open-access MAF lists 31 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 7, Intron 6, RNA 2, Nonsense Mutation 2, 5'UTR 1, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD3 | c.3472C>T p.R1158C (on ENST00000297405 / NM_001363185.1; = p.R1054C on NM_052900.3) | Missense Mutation (SNP) | VAF 225/1446 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396639752, COSV52228178; called by muse, mutect2, varscan2
- CTDNEP1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 387/433 reads (89%) | catalogued as COSV56642845; called by muse, mutect2, varscan2
- GPS2 | c.94+1G>A p.X32_splice | Splice Site (SNP) | VAF 95/246 reads (39%) | catalogued as COSV59747699, COSV59749633; called by muse, mutect2, varscan2
- NR3C1 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 433/1009 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as rs370839677; called by muse, mutect2, varscan2
- SERPINB1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 317/635 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as rs761685123, COSV66313866; called by muse, mutect2, varscan2
- CSE1L | c.2099A>C p.N700T | Missense Mutation (SNP) | VAF 52/992 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- CTSV | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 215/941 reads (23%) | called by muse, mutect2, varscan2
- ERCC6 | c.2197_2198dup p.L734Sfs*6 | Frame Shift Ins (INS) | VAF 240/540 reads (44%) | called by mutect2, varscan2
- FCHSD1 | c.1845del p.E615Dfs*48 | Frame Shift Del (DEL) | VAF 182/426 reads (43%) | called by mutect2, varscan2
- GET3 | c.107G>A p.S36N | Missense Mutation (SNP) | VAF 162/319 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HAL | c.235T>C p.F79L | Missense Mutation (SNP) | VAF 69/531 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- LKAAEAR1 | c.157G>C p.A53P | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- POTEB3 | c.1238G>T p.R413I | Missense Mutation (SNP) | VAF 84/1599 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2
- SPOCK3 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 151/787 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZDHHC8 | c.2172G>T p.Q724H | Missense Mutation (SNP) | VAF 70/1002 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- ALOX5 | c.678C>T p.H226= | Silent (SNP) | VAF 259/850 reads (30%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.228G>A p.G76= | Silent (SNP) | VAF 134/696 reads (19%) | called by muse, mutect2, varscan2
- DEAF1 | c.1032G>A p.S344= | Silent (SNP) | VAF 29/432 reads (7%) | catalogued as rs199746332; called by muse, mutect2
- NLRP7 | c.2169C>T p.F723= (on ENST00000340844 / NM_206828.3; = p.F695= on NM_139176.3) | Silent (SNP) | VAF 284/568 reads (50%) | called by muse, varscan2
- SSUH2 | c.309C>T p.S103= | Silent (SNP) | VAF 106/687 reads (15%) | catalogued as rs578003922, COSV100435712, COSV58030092; called by muse, mutect2, varscan2
- TCOF1 | c.3435C>T p.D1145= (on ENST00000377797 / NM_001135243.1; = p.D1068= on NM_000356.4) | Silent (SNP) | VAF 269/918 reads (29%) | called by muse, mutect2, varscan2
- TUT7 | c.1635C>T p.H545= | Silent (SNP) | VAF 90/536 reads (17%) | called by muse, varscan2
- CCNL1 | c.-8C>T | 5'UTR (SNP) | VAF 32/203 reads (16%) | called by muse, mutect2, varscan2
- DYTN | c.383-35A>T | Intron (SNP) | VAF 112/502 reads (22%) | called by muse, mutect2
- ERCC2 | c.1119-18G>A | Intron (SNP) | VAF 40/733 reads (5%) | catalogued as rs757898467; called by muse, mutect2
- GIT2 | c.1732-76G>A | Intron (SNP) | VAF 7/47 reads (15%) | called by muse, varscan2
- KAT6B | c.1994-44G>T | Intron (SNP) | VAF 40/167 reads (24%) | called by muse, mutect2, varscan2
- METAP2 | c.325+60G>C | Intron (SNP) | VAF 75/337 reads (22%) | called by muse, mutect2, varscan2
- MUC19 | n.10678_10679del | RNA (DEL) | VAF 91/499 reads (18%) | called by mutect2, varscan2
- SSPOP | n.11449C>T | RNA (SNP) | VAF 114/648 reads (18%) | catalogued as rs553671357; called by muse, mutect2, varscan2
- TGFB1 | c.712+45G>A | Intron (SNP) | VAF 105/220 reads (48%) | catalogued as rs72480427; called by muse, mutect2, varscan2
